Somatic mutation profile of tumor specimen TCGA-33-4582-01A (aliquot TCGA-33-4582-01A-01D-1441-08) from TCGA case TCGA-33-4582, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 55.9 years (20,402 days).
Specimen TCGA-33-4582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7647afa8-7317-489a-aa6a-f242ac10abcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4582-11A (Solid Tissue Normal), aliquot TCGA-33-4582-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0063b637-db39-4eb8-9b04-cb8e8f0c0711

The open-access MAF lists 216 somatic variants for this specimen: 155 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 55, Nonsense Mutation 11, Frame Shift Del 3, RNA 3, Intron 2, Frame Shift Ins 2, 3'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 25/36 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.2483C>T p.T828M (on ENST00000326724 / NM_001080395.3; = p.T725M on NM_004920.2) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.513); catalogued as rs753429015, COSV58363703; called by muse, mutect2, varscan2
- ABCB11 | c.2668A>C p.M890L | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55598279; called by muse, mutect2, varscan2
- ADGRB2 | c.4450C>G p.L1484V (on ENST00000373658 / NM_001364857.2; = p.L1483V on NM_001294335.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV57077654; called by muse, mutect2, varscan2
- ANAPC1 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV100594790; called by muse, mutect2, varscan2
- ARHGEF38 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as rs778479538, COSV54444568; called by muse, mutect2, varscan2
- ASTL | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs774176117, COSV60905109; called by muse, mutect2, varscan2
- ASTN2 | c.1250A>T p.Q417L (on ENST00000313400 / NM_001365069.1; = p.Q366L on NM_014010.5) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.775); catalogued as rs1428411278, COSV57810058; called by muse, mutect2, varscan2
- ASXL2 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs781134057, COSV55466033; called by muse, mutect2, varscan2
- ATP8A1 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.268); catalogued as COSV52545579; called by muse, mutect2, varscan2
- BBX | c.1611A>C p.K537N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57892526; called by muse, mutect2, varscan2
- BIRC6 | c.14387C>G p.A4796G | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs1413601974, COSV70204279; called by muse, mutect2, varscan2
- BPIFB1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374640604; called by muse, mutect2, varscan2
- BPIFB1 | c.1333G>T p.G445W | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53608385; called by muse, varscan2
- C2orf16 | c.10A>C p.T4P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV68842583; called by muse, mutect2, varscan2
- CA11 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50033975; called by muse, mutect2, varscan2
- CABLES2 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54158088; called by muse, mutect2, varscan2
- CDH7 | c.194C>G p.P65R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV59892503; called by muse, mutect2
- CDYL2 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV73654719; called by muse, mutect2, varscan2
- CFAP206 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV51536496; called by muse, mutect2, varscan2
- CHST5 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60341154; called by muse, mutect2, varscan2
- CIP2A | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV55420739; called by muse, mutect2, varscan2
- CLDN25 | c.542T>A p.L181Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); catalogued as COSV71620474; called by muse, mutect2, varscan2
- COL15A1 | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1314696960, COSV66648181, COSV66648349; called by muse, mutect2, varscan2
- COL6A6 | c.2341T>A p.F781I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62034568; called by muse, mutect2, varscan2
- CREB3L4 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV55133073; called by muse, mutect2, varscan2
- CSE1L | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 96/143 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs763077862, COSV53702091, COSV53704428; called by muse, varscan2
- CSMD3 | c.8327C>A p.S2776* (on ENST00000297405 / NM_001363185.1; = p.S2607* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 34/112 reads (30%) | catalogued as COSV52160972, COSV52287189; called by muse, mutect2, varscan2
- CSPP1 | c.3169G>C p.E1057Q (on ENST00000676605; = p.E1016Q on NM_024790.6) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as COSV51590972; called by muse, mutect2, varscan2
- DAGLB | c.32G>T p.W11L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51703428; called by mutect2, varscan2
- DAPK3 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199653811, COSV56662606; called by muse, mutect2, varscan2
- DCAF1 | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV60045929; called by muse, mutect2, varscan2
- DCAF12L1 | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.681); catalogued as COSV64421683, COSV64422612; called by muse, mutect2, varscan2
- DDIT4 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV56578025; called by muse, mutect2, varscan2
- DDX1 | c.1325A>T p.H442L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51842700; called by muse, mutect2, varscan2
- DNAI2 | c.1508A>T p.E503V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56761890; called by muse, mutect2, varscan2
- DSN1 | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65520004; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1189G>A p.D397N (on ENST00000361735 / NM_015935.5; = p.D311N on NM_014955.3) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs994612616, COSV62283693; called by muse, mutect2, varscan2
- FAM210A | c.585G>A p.K195= | Splice Region (SNP) | VAF 14/78 reads (18%) | catalogued as COSV59185767; called by muse, mutect2, varscan2
- FAT1 | c.8669C>T p.S2890L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV71671643, COSV71675563; called by muse, mutect2, varscan2
- FBN1 | c.5363G>T p.S1788I | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57327549; called by muse, mutect2, varscan2
- FCRL1 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV63824217, COSV63825106, COSV63826906; called by muse, mutect2, varscan2
- FUT6 | c.700A>T p.M234L | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54607754; called by muse, mutect2, varscan2
- FZD4 | c.1336G>C p.V446L | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1401889016, COSV72294650; called by muse, mutect2
- GET4 | c.911G>C p.S304T | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as COSV56216677; called by muse, mutect2, varscan2
- GK | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 58/82 reads (71%) | catalogued as COSV66734753; called by muse, mutect2, varscan2
- GRIN2A | c.1381A>T p.I461F | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58052388; called by muse, mutect2, varscan2
- GTF2H3 | c.126G>C p.M42I | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.75); PolyPhen benign (0.023); catalogued as COSV57459746; called by muse, mutect2, varscan2
- HOXD3 | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV50884664; called by muse, mutect2
- HSP90AA1 | c.54G>C p.E18D | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV53490896; called by muse, mutect2, varscan2
- IFT122 | c.1853C>T p.S618F (on ENST00000348417 / NM_052989.3; = p.S559F on NM_018262.4) | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1371012508, COSV56204581; called by muse, mutect2, varscan2
- IL18RAP | c.376T>A p.C126S | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51828520; called by muse, mutect2
- INTS1 | c.5128G>T p.G1710W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV67179251; called by muse, mutect2, varscan2
- ITPRID1 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV60081101; called by muse, mutect2, varscan2
- KCNK1 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64036094; called by muse, mutect2, varscan2
- KCNRG | c.212T>C p.L71S | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV53950187, COSV53951248; called by muse, mutect2, varscan2
- KCTD6 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57150430; called by muse, mutect2, varscan2
- KLHL36 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1349201513, COSV50722409; called by muse, mutect2, varscan2
- KLK15 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56826573; called by muse, mutect2, varscan2
- LIPJ | c.728G>C p.R243P | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64246102; called by muse, mutect2, varscan2
- LRRC7 | c.1399C>A p.Q467K (on ENST00000651989 / NM_001370785.2; = p.Q434K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50577329; called by muse, mutect2, varscan2
- LSM8 | c.40G>C p.A14P | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.266); catalogued as COSV50800367, COSV50800692; called by muse, varscan2
- LUC7L3 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV53588995; called by muse, mutect2, varscan2
- MACC1 | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV60545684; called by muse, mutect2, varscan2
- MASTL | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100668965, COSV60912248; called by muse, mutect2, varscan2
- MB21D2 | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66665522; called by muse, mutect2, varscan2
- MDM2 | c.1339T>A p.C447S | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50702374; called by muse, mutect2, varscan2
- MDN1 | c.12166C>T p.R4056C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs766113682, COSV65525776; called by muse, mutect2, varscan2
- METTL8 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV64549289; called by muse, mutect2, varscan2
- MGAM | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075407; called by muse, mutect2, varscan2
- MIEN1 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.022); catalogued as COSV54079582; called by muse, mutect2, varscan2
- MINDY4 | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54677630; called by muse, mutect2, varscan2
- MMP12 | c.372C>A p.D124E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100404802, COSV58261073; called by muse, mutect2, varscan2
- MYCBP2 | c.7294A>C p.K2432Q (on ENST00000357337; = p.K2470Q on NM_015057.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV62035266; called by muse, mutect2, varscan2
- MYH4 | c.1931A>G p.K644R | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV55124447; called by muse, mutect2, varscan2
- MYH9 | c.1407C>G p.I469M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV53391705; called by muse, mutect2, varscan2
- MYT1L | c.1916A>C p.Y639S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV67729748; called by muse, mutect2, varscan2
- MYT1L | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV67729755; called by muse, mutect2
- NKTR | c.3130G>C p.V1044L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV51774533; called by muse, mutect2
- NLGN4X | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV52032620; called by muse, mutect2, varscan2
- NPL | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV51126818; called by muse, mutect2, varscan2
- NUCB1 | c.867G>T p.M289I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs569947634, COSV54387947; called by muse, mutect2, varscan2
- OCA2 | c.2446A>T p.M816L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62355603; called by muse, mutect2, varscan2
- OMP | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs370927367; called by muse, mutect2, varscan2
- OPN1SW | c.892T>G p.Y298D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50822953; called by muse, mutect2, varscan2
- OR4N5 | c.212C>G p.A71G | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV61321159; called by muse, varscan2
- OR5AC2 | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62280021; called by muse, varscan2
- OR5AC2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 52/452 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62280026; called by muse, varscan2
- OR5H2 | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.156); catalogued as COSV62351679; called by muse, mutect2, varscan2
- P3H3 | c.1859A>G p.Q620R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV51835772; called by muse, mutect2, varscan2
- PARP1 | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs745820900, COSV64691817; called by muse, mutect2, varscan2
- PCDH15 | c.4528G>T p.A1510S | Missense Mutation (SNP) | VAF 83/120 reads (69%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.015); catalogued as COSV57375883; called by muse, mutect2, varscan2
- PDE3B | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56389312; called by muse, mutect2, varscan2
- PELI1 | c.167C>G p.T56S | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.065); catalogued as COSV62730721; called by muse, mutect2, varscan2
- PER1 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV57922489; called by muse, mutect2
- PIK3AP1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536108; called by muse, mutect2, varscan2
- PKHD1 | c.8545G>T p.G2849* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as COSV61890714; called by muse, mutect2, varscan2
- PLD1 | c.2761G>T p.G921* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as COSV60572942; called by muse, mutect2, varscan2
- PLXNA2 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs762107117, COSV65440539; called by muse, mutect2, varscan2
- PLXNC1 | c.3952G>A p.D1318N | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51581651; called by muse, mutect2, varscan2
- PM20D1 | c.525G>T p.R175S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV65649007, COSV65649483; called by muse, mutect2, varscan2
- PNLDC1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1209308204, COSV51703622, COSV51707507; called by muse, mutect2, varscan2
- PNLIPRP2 | c.965G>C p.G322A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV53945012, COSV53946034; called by muse, mutect2, varscan2
- PRDM5 | c.1461G>T p.K487N | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53365793; called by muse, mutect2, varscan2
- PTCD1 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52866880; called by muse, mutect2, varscan2
- PTOV1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs762322759, COSV55586990; called by muse, mutect2, varscan2
- RAI2 | c.663G>T p.L221F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58965875; called by muse, mutect2, varscan2
- RIMS2 | c.1486C>A p.P496T (on ENST00000666250 / NM_001348490.2; = p.P304T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as COSV51714543; called by muse, mutect2, varscan2
- RLIM | c.1135G>T p.V379F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60328611; called by muse, mutect2, varscan2
- RNF157 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53947591; called by muse, varscan2
- RPA2 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57878611; called by muse, mutect2, varscan2
- RUFY3 | c.1718A>C p.K573T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV66816352; called by muse, mutect2
- SCN3A | c.715del p.A239Pfs*2 | Frame Shift Del (DEL) | VAF 68/232 reads (29%) | catalogued as COSV51810229; called by mutect2, pindel, varscan2
- SEMA5A | c.2218C>G p.P740A | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV66803177, COSV66805228; called by muse, mutect2, varscan2
- SENP7 | c.3064C>A p.P1022T | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58610082, COSV58617012; called by muse, mutect2, varscan2
- SIGLEC8 | c.75T>A p.D25E | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58475438; called by muse, mutect2, varscan2
- SLC15A3 | c.1345G>T p.V449F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs773963568, COSV50018540; called by muse, mutect2, varscan2
- SLC2A2 | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as COSV58588111; called by muse, varscan2
- SLC4A5 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV61031775; called by muse, mutect2
- SLC6A3 | c.1549A>T p.S517C | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54368480; called by muse, mutect2, varscan2
- SMC1B | c.615+1G>T p.X205_splice | Splice Site (SNP) | VAF 5/53 reads (9%) | catalogued as COSV62532791; called by muse, mutect2, varscan2
- SPEN | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV65360498, COSV65361858; called by muse, mutect2, varscan2
- SSC4D | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51883775; called by muse, mutect2, varscan2
- SSTR4 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1420818755, COSV54797606; called by muse, mutect2, varscan2
- STAC2 | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV61066458; called by muse, mutect2, varscan2
- STXBP5 | c.1739A>T p.Q580L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.098); catalogued as COSV51656701; called by muse, mutect2, varscan2
- SYNE1 | c.2594G>A p.C865Y (on ENST00000367255 / NM_182961.4; = p.C872Y on NM_033071.3) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229969547, COSV55073390; called by muse, mutect2, varscan2
- TARS1 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54311769; called by muse, mutect2, varscan2
- TBX21 | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV51597676; called by muse, mutect2
- THEMIS | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64073682; called by muse, mutect2, varscan2
- THSD7B | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.425); catalogued as rs1375683866, COSV55727191; called by muse, mutect2, varscan2
- TMEM176B | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV50244294; called by muse, mutect2, varscan2
- TOX3 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV54872036; called by muse, mutect2, varscan2
- TRIM9 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 124/393 reads (32%) | catalogued as COSV53623649; called by muse, mutect2, varscan2
- TRIOBP | c.3151C>T p.P1051S | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60383120; called by muse, mutect2, varscan2
- TTC21B | c.2660G>C p.C887S | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54634064; called by muse, mutect2, varscan2
- TTN | c.87494C>T p.A29165V (on ENST00000591111; = p.A21741V on NM_003319.4) | Missense Mutation (SNP) | VAF 37/94 reads (39%) | PolyPhen benign (0.073); catalogued as COSV60278847; called by muse, mutect2, varscan2
- TTN | c.48569A>G p.Q16190R (on ENST00000591111; = p.Q8766R on NM_003319.4) | Missense Mutation (SNP) | VAF 29/382 reads (8%) | PolyPhen benign (0.098); catalogued as COSV60278871; called by muse, mutect2
- TUBA3C | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.412); catalogued as COSV67139850; called by muse, mutect2, varscan2
- UNC5D | c.1901A>T p.H634L | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54826722; called by muse, mutect2
- USH2A | c.12835C>T p.Q4279* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV56420420; called by muse, mutect2, varscan2
- VRK2 | c.1013A>C p.N338T | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV60879674; called by muse, mutect2, varscan2
- WDR72 | c.2416G>T p.G806* | Nonsense Mutation (SNP) | VAF 126/381 reads (33%) | catalogued as rs772603639, COSV64752513, COSV64753978; called by muse, mutect2, varscan2
- ZFYVE1 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1443848261, COSV59612602; called by muse, mutect2, varscan2
- ZNF211 | c.481G>A p.A161T (on ENST00000347302 / NM_198855.4; = p.A174T on NM_006385.5) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV53744763; called by muse, mutect2, varscan2
- ZNF267 | c.1367C>G p.T456R | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56255646; called by muse, mutect2, varscan2
- ZNF394 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV61794360; called by muse, mutect2, varscan2
- ZNF506 | c.1221C>G p.N407K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV71354616; called by muse, mutect2, varscan2
- AHNAK | c.5815dup p.D1939Gfs*24 | Frame Shift Ins (INS) | VAF 46/284 reads (16%) | called by mutect2, pindel, varscan2
- COL8A1 | c.750_766del p.P251Sfs*105 | Frame Shift Del (DEL) | VAF 18/183 reads (10%) | called by mutect2, pindel
- GAP43 | c.245dup p.E83Rfs*17 | Frame Shift Ins (INS) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- GEMIN5 | c.3373del p.E1125Sfs*36 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- IGKV2-30 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MAGEB4 | c.104A>T p.K35I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.093); called by muse, mutect2
- XKR3 | c.1244A>G p.N415S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.9690G>C p.T3230= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as COSV52182636; called by muse, mutect2, varscan2
- AP1M1 | c.219G>A p.K73= | Silent (SNP) | VAF 49/203 reads (24%) | catalogued as COSV52228423; called by muse, mutect2, varscan2
- BMS1 | c.477G>T p.G159= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as rs781270816, COSV65735154; called by muse, mutect2, varscan2
- CADPS | c.2862G>A p.L954= | Silent (SNP) | VAF 122/227 reads (54%) | catalogued as rs768598090, COSV51897801; called by muse, mutect2, varscan2
- CCNB3 | c.1383A>T p.P461= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV52078522; called by muse, mutect2, varscan2
- CD163L1 | c.96G>A p.L32= | Silent (SNP) | VAF 83/215 reads (39%) | catalogued as rs910724617, COSV58019052, COSV58022959; called by muse, mutect2, varscan2
- CIAO3 | c.1311G>A p.G437= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV52404001; called by muse, mutect2, varscan2
- CNTN2 | c.1296C>A p.R432= | Silent (SNP) | VAF 88/222 reads (40%) | catalogued as COSV59352289; called by muse, mutect2, varscan2
- COPZ2 | c.558C>T p.G186= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs368840240; called by muse, varscan2
- CP | c.900C>T p.H300= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs757188910, COSV52833177; called by muse, mutect2, varscan2
- CYP4F2 | c.1464C>T p.R488= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs765151224, COSV55620823; called by muse, varscan2
- DHX35 | c.1167G>A p.Q389= | Silent (SNP) | VAF 165/266 reads (62%) | catalogued as COSV52673405; called by muse, mutect2, varscan2
- DIP2A | c.2703C>T p.P901= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59484939; called by muse, mutect2, varscan2
- DMRTA1 | c.777G>T p.G259= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV57924963; called by muse, mutect2, varscan2
- DNAH7 | c.4341C>A p.L1447= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV56770420, COSV56780506; called by muse, mutect2, varscan2
- EXPH5 | c.3240A>G p.E1080= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV56203819, COSV56207101; called by muse, mutect2, varscan2
- FBXL3 | c.1278C>G p.P426= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV62919233; called by muse, mutect2, varscan2
- FH | c.885A>G p.A295= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs199635833, COSV63818805; called by muse, mutect2, varscan2
- GRIK2 | c.72G>A p.L24= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs779499175, COSV59762568; called by muse, mutect2, varscan2
- JUP | c.1950C>T p.F650= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV60279404; called by muse, mutect2, varscan2
- KAT6B | c.6129C>T p.H2043= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs759909977, COSV54741313; called by muse, mutect2, varscan2
- KCNH1 | c.1383C>T p.L461= (on ENST00000271751 / NM_172362.3; = p.L434= on NM_002238.4) | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV55097821; called by muse, mutect2, varscan2
- KCNK10 | c.964C>T p.L322= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs1375343407, COSV56650808; called by muse, mutect2, varscan2
- KIF18A | c.2088T>C p.L696= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as COSV54186736; called by muse, mutect2, varscan2
- LDHD | c.750G>C p.G250= | Silent (SNP) | VAF 76/132 reads (58%) | catalogued as COSV55581770; called by muse, mutect2, varscan2
- LMTK2 | c.2745G>T p.G915= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs570314330, COSV52002265; called by muse, mutect2, varscan2
- MAP1B | c.891C>G p.L297= | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as COSV57104651; called by muse, mutect2, varscan2
- MYH3 | c.2637G>A p.V879= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV56864982, COSV56869040; called by muse, mutect2, varscan2
- MYRIP | c.2220G>A p.Q740= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV56878952; called by muse, mutect2, varscan2
- NMUR2 | c.102C>T p.A34= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV54921815; called by muse, mutect2, varscan2
- NUP160 | c.2298A>G p.T766= | Silent (SNP) | VAF 53/82 reads (65%) | catalogued as rs1396182869, COSV65855606; called by muse, mutect2, varscan2
- ODF3L2 | c.735A>T p.P245= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV52748763; called by muse, mutect2
- OR8U1 | c.78C>A p.P26= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as COSV100163925; called by muse, mutect2, varscan2
- PADI4 | c.750C>T p.Y250= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs1207131421, COSV64923020; called by muse, mutect2, varscan2
- PCDH15 | c.3498G>T p.V1166= | Silent (SNP) | VAF 41/74 reads (55%) | catalogued as COSV57375899; called by muse, mutect2, varscan2
- PCDHA7 | c.1086C>T p.D362= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV65342342; called by muse, mutect2, varscan2
- PHACTR2 | c.786G>T p.G262= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV59857680; called by muse, mutect2, varscan2
- PLCH1 | c.2094C>T p.F698= (on ENST00000340059 / NM_001130960.2; = p.F710= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV58206942; called by muse, mutect2, varscan2
- PLD1 | c.2760G>T p.L920= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV60572952; called by muse, mutect2, varscan2
- POLQ | c.7627C>T p.L2543= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV51759349; called by muse, mutect2
- PPIG | c.1893A>T p.S631= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV53645453; called by muse, mutect2
- PXDNL | c.1083C>A p.I361= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV62496410; called by muse, mutect2, varscan2
- RAB6A | c.570C>T p.D190= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs765960811, COSV60179802; called by muse, mutect2, varscan2
- RB1CC1 | c.1566A>G p.K522= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV50268941; called by muse, mutect2, varscan2
- SDHB | c.840T>G p.V280= | Silent (SNP) | VAF 62/223 reads (28%) | catalogued as COSV64965630; called by muse, mutect2, varscan2
- SLC30A8 | c.987G>A p.V329= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV69971951; called by muse, mutect2, varscan2
- SLC39A6 | c.270C>A p.I90= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV52370889; called by muse, mutect2
- SPEF2 | c.1935A>T p.S645= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV61552548; called by muse, mutect2, varscan2
- SYT2 | c.408G>A p.E136= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV66142833; called by muse, mutect2, varscan2
- SYT2 | c.165A>C p.I55= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV66142839; called by muse, mutect2, varscan2
- TAS2R1 | c.330C>T p.V110= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV66779288; called by muse, mutect2, varscan2
- TRMT61B | c.90G>A p.E30= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV60258720; called by muse, mutect2, varscan2
- ZFYVE26 | c.4431G>A p.L1477= | Silent (SNP) | VAF 14/189 reads (7%) | catalogued as COSV61332581; called by muse, mutect2
- ZKSCAN3 | c.72C>T p.V24= | Silent (SNP) | VAF 108/173 reads (62%) | catalogued as COSV52854079; called by muse, mutect2, varscan2
- ZNF846 | c.408C>T p.H136= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV67412508; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506432 del TTAACAATT | 3'Flank (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- EIF5 | c.440-443G>C | Intron (SNP) | VAF 27/107 reads (25%) | catalogued as rs774027834, COSV99384650, COSV99384852; called by muse, mutect2, varscan2
- MIR329-1 | n.13G>T | RNA (SNP) | VAF 35/169 reads (21%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109728C>A | Intron (SNP) | VAF 22/98 reads (22%) | catalogued as COSV58454765, COSV58483796; called by muse, mutect2, varscan2
- SFTA3 | n.856C>T | RNA (SNP) | VAF 23/156 reads (15%) | catalogued as rs745769793, COSV69488916; called by muse, mutect2, varscan2
- SNX29P2 | n.1064G>A | RNA (SNP) | VAF 7/62 reads (11%) | catalogued as rs761801866; called by muse, mutect2, varscan2
